Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17D-01A (Primary Tumor).

[page 1 of 4]
Adenocarcinoma, Endometrioid, NOS

8380/3

12/9/10

hr

Site code: Endometrium C54.1

Surgical Pathology

DIAGNOSIS:

A. Uterus, bilateral tubes and ovaries, hysterectomy and
bilateral
salpingo-oophorectomy: FIGO grade III (of III)
endometrial
adenocarcinoma, endometrioid type, is identified forming a
mass (5.2

x 4.0 x 2.3 cm), involving nearly the entire endometrial
cavity.

The tumor invades a maximum depth of 0.8 cm into the
myometrium

(total wall thickness, 1.2 cm). The tumor does not
involve the

endocervix. Lymphovascular space invasion is not
identified. The

margins are negative for tumor. Multiple (2) submucosal
intramural

leiomyomata (ranging in size from 0.3 cm to 1.5 cm in
greatest

dimension) are identified. The cervix shows mild chronic
cervicitis. Bilateral ovaries and fallopian tubes are
without

diagnostic abnormality. [AJCCpT1cNOMX]

B. Lymph nodes, right and left pelvic, excision:

Multiple (23)

right and left pelvic lymph nodes are negative for tumor.

C. D. Lymph nodes, right para-aortic, excision: Multiple
(6 above

and 3 below the inferior mesenteric artery) are negative
for tumor.

E. F. Lymph nodes, left para-aortic, excision: Multiple
left

para-aortic lymph nodes (19 above and 7 below the inferior
mesenteric artery) are negative for tumor

**GROSS DESCRIPTION:**

A. Received fresh labeled "uterus and bilateral tubes and
ovaries"

[page 2 of 4]
is a 70.0 gram uterus with attached bilateral tubes and ovaries and a hemorrhagic cervix. The uterine serosa is smooth. There is a 5.2 x 4.0 x 2.3 cm mass in the entire endometrial cavity with 1.2 cm myometrial thickness. There are 2 uterine submucosal intramural leiomyomas ranging from 0.3 cm to 1.5 cm. There is a 1.7 x 1.5 x 0.9 cm right ovary with a smooth outer surface and a solid cut surface with a 6.8 x 0.8 cm right fallopian tube. There is a 2.7 x 1.7 x 0.9 cm left ovary with a smooth outer surface and a solid cut surface with a 6.5 x 0.8 cm left fallopian tube. Representative sections are submitted.

B. Received fresh labeled "right and left pelvic lymph nodes" is a 9.1 x 5.6 x 2.3 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

C. Received fresh labeled "right gonadal vessels" is an 11.5 cm in length by 0.3 cm in diameter portion of unremarkable blood vessel. Tumor is identified in the lumen. A representative section is submitted.

D. Received fresh labeled "right para-aortic lymph nodes below the inferior mesenteric artery" is a 2.6 x 1.3 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "right para-aortic lymph nodes above the inferior mesenteric artery" is a 3.2 x 2.3 x 1.1 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 3 of 4]
F. Received fresh labeled "left para-aortic lymph nodes above the inferior mesenteric artery" is a 7.0 x 3.5 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

G. Received fresh labeled "left para-aortic lymph nodes below the inferior mesenteric artery" is a 4.5 x 2.5 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

BLOCK SUMMARY:

Part A: Uterus, tubes, ovaries

- 1 Endometrial mass-1
- 2 Endometrial mass-2
- 3 Endometrial mass-3
- 4 Endometrial mass-4
- 5 Endometrial mass-5
- 6 Endometrial mass-6
- 7 Rt ovary
- 8 Rt fallopian tube
- 9 Lt ovary
- 10 Lt fallopian tube
- 11 Lower uterine segment
- 12 Cervix

Part B: Right and left pelvic lymph nodes

- 1 Rt & Lt pelvic lns 2 (B1)
- 2 Rt & Lt pelvic lns 2 (B2)
- 3 Rt & Lt pelvic lns 1 (B3)
- 4 Rt & Lt pelvic lns 1 (B4)
- 5 Rt & Lt pelvic lns 1of2 (B5)
- 6 Rt & Lt pelvic lns 2of2 (B5)
- 7 Rt & Lt pelvic LNs-2 (B6)
- 8 Rt & Lt pelvic LNs-2 (B7)
- 9 Rt & Lt pelvic LN(1of2) (B8)
- 10 Rt & Lt pelvic LN(2of2) (B8)
- 11 Rt & Lt pelvic LNs-2 (B9)
- 12 Rt&Lt pelvic LN(1of3) (B10)
- 13 Rt&Lt pelvic LN(2of3) (B10)
- 14 Rt&Lt pelvic LN(3of3) (B10)
- 15 Rt & Lt pelvic LNs-2 (B11)

[page 4 of 4]
- 16 Rt & Lt pelvic LNs-2(B12)
- 17 Rt & Lt pelvic LNs-2(B13)

Part C: Right gonadal vessel
1 Right gonadal vessel

Part D: Right para-aortic lymph nodes below IMA
1 Rt PA LN below IMA 2(D1)

Part E: Right para-aortic lymph nodes above IMA
1 Rt PA LN above IMA 1(E1)
2 Rt PA LN above IMA 1(E2)

Part F: Left Para-aortic Lymph Nodes above IMA
1 Lt PA above IMA 4 (F1)
2 Lt PA above IMA 1 (F2)
3 Lt PA above IMA 2 (F3)
4 Lt PA above IMA 1of2 (F4)
5 Lt PA above IMA 2of2 (F4)
6 Lt PA above IMA 1 (F5)
7 Lt PA above IMA 2 (F6)
8 Lt PA above IMA 5 (F7)

Part G: Left Para-aortic Lymph Nodes below IMA
1 Lt PA below IMA 2 (G1)
2 Lt PA below IMA 2 (G2)
3 Lt PA below IMA 1 (G3)
4 Lt PA below IMA 1 (G4)

Source: NCI Genomic Data Commons file effc89b1-ddd1-4a07-96a3-36b8a1b7fdec (TCGA-D1-A17D.1042404C-E963-4620-BC02-E33751FDB96C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).